Gene-level copy-number profile of tumor specimen HTMCP-03-06-02175-01A from CGCI case HTMCP-03-06-02175, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 38.3 years (14,007 days).
Specimen HTMCP-03-06-02175-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0c5de025-e6c0-4f81-bb26-a896eee958bb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02175-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,246 have no estimate.
https://portal.gdc.cancer.gov/files/a86c24b3-f46b-4dbc-b15f-44a313cc2ff9

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 1,992; copy number 2: 18,297; copy number 3: 22,767; copy number 4: 10,577; copy number 5: 3,995; copy number 6: 586; copy number 7: 122; copy number 8: 9; copy number 9: 1; copy number 14: 1; copy number 16: 2; copy number 23: 2.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:129,988,158–130,028,412, 2 genes (within-gene range 0–2): AC079776.3, AC079776.4.
- chr2:130,006,200–130,051,131, 5 genes: ARHGAP42P2, FAR2P1, AC018865.2, KLF2P1, CYP4F27P.
- chr11:86,649–186,136, 6 genes (within-gene range 0–2): OR4F2P, AC069287.1, CICP23, LINC01001, AC069287.3, RNU6-447P.
- chr11:4,242,056–4,339,244, 5 genes: SSU72P2, SSU72P6, SSU72P4, SSU72P3, SSU72P7.
- chr11:55,602,360–55,686,160, 7 genes: OR4C11, OR4P4, OR4S2, OR4C6, OR4V1P, OR4P1P, AP006437.1.
- chr13:63,975,451–63,976,422, 1 gene: NFYAP1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 137 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:34,554–71,585, 4 genes, copy number 7: FAM138A, OR4G4P, OR4G11P, OR4F5.
- chr1:266,855–522,928, 9 genes, copy number 8: AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6.
- chr8:102,805,517–104,256,094, 34 genes, copy number 7: GASAL1, AZIN1, AP003696.1, MAILR, AP003354.1, RPL5P24, Y_RNA, NPM1P52, AP003550.1, ATP6V1C1, MTND1P5, MTCO1P4, MTCO2P4, LINC01181, BAALC-AS2, BAALC, BAALC-AS1, MIR3151, AC025370.1, FZD6, AC025370.2, CTHRC1, AC012213.3, RNU6-1011P, SLC25A32, AC012213.5, DCAF13, AC012213.2, AC012213.4, AC012213.1, RIMS2, PTMAP15, AC007751.1, AC090686.1.
- chr8:131,712,512–135,742,495, 60 genes, copy number 7: AC060788.1, EFR3A, OC90, AC100868.1, HHLA1, KCNQ3, HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2, AC105180.2, AC105180.1, ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1, AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56, LINC01591, AC040914.1, KHDRBS3, MAPRE1P1, RNU1-35P.
- chr10:13,277,796–13,348,298, 3 genes, copy number 9–23: PHYH, RBISP1, SEPHS1.
- chr12:57,623,409–57,896,846, 24 genes, copy number 7 (within-gene range 5–7): B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3.
- chr16:26,721,874–26,729,126, 1 gene, copy number 14: AC009035.1.
- chr18:68,258,080–68,278,243, 2 genes, copy number 16: LINC01912, AC022968.1.

Autosomal genes at a single copy (total copy number 1): 1,992. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
